Somatic mutation profile of tumor specimen TCGA-QS-A5YR-01A (aliquot TCGA-QS-A5YR-01A-31D-A31U-09) from TCGA case TCGA-QS-A5YR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 61.3 years (22,372 days).
Specimen TCGA-QS-A5YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93aefac7-6017-42fe-90a0-40f77ad602aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QS-A5YR-10A (Blood Derived Normal), aliquot TCGA-QS-A5YR-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/087493a1-4d6f-4a12-be85-e3684e35293f

The open-access MAF lists 309 somatic variants for this specimen: 234 protein-altering or splice-affecting, 70 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 142, Silent 70, Frame Shift Del 62, Frame Shift Ins 15, Nonsense Mutation 9, In Frame Del 3, Splice Region 2, 5'UTR 1, Splice Site 1, 3'UTR 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- NFE2L2 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 43/145 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553487942, COSV67960075, COSV67960449, COSV67960680; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS12 | c.412del p.L138Sfs*26 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as COSV100711524, COSV61261596; called by mutect2, pindel, varscan2
- AGO2 | c.2374C>T p.R792C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1405802563, COSV55053357; called by muse, mutect2, varscan2
- ALDH8A1 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs920336778, COSV99664353; called by muse, mutect2, varscan2
- ALX1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765386152, COSV100374254; called by muse, mutect2, varscan2
- AMIGO3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100246397; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4594del p.R1532Gfs*5 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as COSV51845823; called by mutect2, pindel, varscan2
- ANKRD13B | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.464); catalogued as rs1403646075, COSV100801076; called by muse, mutect2
- ARID1A | c.5503C>T p.Q1835* | Nonsense Mutation (SNP) | VAF 3/8 reads (38%) | catalogued as COSV61376714; called by muse, mutect2
- ART1 | c.735dup p.F246Lfs*2 | Frame Shift Ins (INS) | VAF 9/28 reads (32%) | catalogued as rs762428866; called by mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ATAD2 | c.3215G>A p.R1072H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); catalogued as COSV54882664; called by muse, mutect2, varscan2
- ATAD2B | c.2303G>A p.R768H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53198340; called by muse, mutect2, varscan2
- BAG6 | c.1589G>T p.G530V (on ENST00000676571; = p.G483V on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV99276266; called by muse, mutect2, varscan2
- BCAS3 | c.119T>C p.L40P | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101174907; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs752427670; called by mutect2, varscan2
- BRCA2 | c.791A>G p.H264R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as COSV101203838; called by muse, mutect2
- BRD2 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV100875537; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 9/19 reads (47%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- C1orf112 | c.1945-1G>T p.X649_splice | Splice Site (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99609283; called by muse, mutect2, varscan2
- CACNA1A | c.6173del p.P2058Lfs*70 | Frame Shift Del (DEL) | VAF 21/82 reads (26%) | catalogued as CD040162; called by mutect2, pindel, varscan2
- CASR | c.2573C>T p.P858L (on ENST00000490131; = p.P935L on NM_000388.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs201950717, COSV56134409; called by muse, mutect2, varscan2
- CATSPER1 | c.2260C>T p.Q754* | Nonsense Mutation (SNP) | VAF 9/13 reads (69%) | catalogued as COSV100375528; called by muse, mutect2, varscan2
- CD55 | c.791C>G p.S264C | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100132210; called by muse, mutect2, varscan2
- CDC42BPB | c.398G>A p.C133Y | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.32); catalogued as rs978392521, COSV100775086; called by muse, mutect2
- CDH17 | c.1744G>T p.G582C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99216832; called by muse, mutect2, varscan2
- CDH20 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99404043; called by muse, mutect2, varscan2
- CDH23 | c.9495C>A p.S3165R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99818380; called by muse, mutect2
- CDHR2 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs770196822, COSV99990896; called by muse, mutect2, varscan2
- CDK5 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52521055; called by muse, mutect2, varscan2
- CEBPD | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770705158, COSV99854014; called by muse, mutect2, varscan2
- CEP112 | c.1523A>G p.E508G | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV101210428; called by muse, mutect2, varscan2
- CHD3 | c.1957T>C p.W653R | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100390546; called by muse, mutect2, varscan2
- CHD6 | c.5594A>G p.D1865G | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV100950483; called by muse, mutect2, varscan2
- CHD8 | c.6025C>T p.P2009S (on ENST00000646647 / NM_001170629.2; = p.P1730S on NM_020920.4) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs1294224989, COSV100765233; called by muse, mutect2, varscan2
- COL19A1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753339843, COSV100505938, COSV59571242; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2962G>A p.V988M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as rs1463730032, COSV99267250; called by muse, mutect2, varscan2
- COX4I2 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs748714176, COSV65781862; called by muse, mutect2, varscan2
- CPNE1 | c.1129C>T p.R377C (on ENST00000352393; = p.R382C on NM_003915.5) | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs772303395, COSV100466873; called by muse, mutect2, varscan2
- CSF2RB | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV53255417, COSV99453140; called by muse, mutect2, varscan2
- CTTNBP2 | c.2672A>G p.E891G | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV99352746; called by muse, mutect2, varscan2
- CUBN | c.3389C>T p.P1130L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100911929; called by muse, mutect2, varscan2
- CUL3 | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52373053; called by muse, mutect2, varscan2
- CUL9 | c.6026C>T p.T2009M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs202019331, COSV99334588; called by muse, mutect2, varscan2
- CYP2A6 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV99991697; called by muse, mutect2, varscan2
- CYP4F8 | c.111G>T p.W37C | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100357971; called by muse, mutect2, varscan2
- DEDD2 | c.458del p.P153Qfs*42 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs758890887, COSV60141885; called by mutect2, pindel, varscan2
- DHX16 | c.1994C>A p.P665H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100905125; called by muse, mutect2, varscan2
- DHX38 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99194176; called by muse, mutect2, varscan2
- DLL1 | c.599G>A p.G200D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100815884; called by muse, mutect2, varscan2
- DNAI4 | c.89del p.K30Rfs*28 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | catalogued as rs774662919; called by mutect2, pindel, varscan2
- DNAJC10 | c.804A>C p.G268= | Splice Region (SNP) | VAF 11/47 reads (23%) | catalogued as COSV99898816; called by muse, mutect2, varscan2
- DROSHA | c.3589C>T p.Q1197* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | catalogued as rs1289997268, COSV100757434; called by muse, mutect2, varscan2
- DYSF | c.3846G>A p.P1282= | Splice Region (SNP) | VAF 8/33 reads (24%) | catalogued as rs772742658, COSV50319705; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZIP3 | c.3497C>T p.A1166V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1352288703, COSV100847561; called by muse, mutect2, varscan2
- EDIL3 | c.1430C>T p.T477I | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1170417802, COSV56894791; called by muse, mutect2, varscan2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF4G2 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs780085043, COSV60597446; called by muse, mutect2, varscan2
- EPG5 | c.5354G>A p.R1785H | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99956325; called by muse, mutect2, varscan2
- EPHB3 | c.1405C>A p.L469I | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.492); catalogued as COSV100382738; called by muse, mutect2
- FAT3 | c.10873G>T p.G3625C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960509; called by muse, mutect2, varscan2
- FBXO5 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs756791089, COSV99999623; called by mutect2, varscan2
- FEN1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs371695318; called by muse, mutect2, varscan2
- FUBP1 | c.1129C>T p.Q377* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99627554; called by muse, mutect2, varscan2
- GABBR2 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.984); catalogued as rs764365066, COSV52297056; ClinVar: uncertain significance; called by muse, mutect2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs758551787; called by mutect2, varscan2
- GLUL | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs749858846, COSV100091731; called by muse, mutect2, varscan2
- GPSM1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV61303810; called by muse, mutect2, varscan2
- GRK7 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs752712684, COSV99379465; called by muse, mutect2, varscan2
- HDX | c.209C>T p.T70I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as rs1284245399, COSV99946410; called by muse, mutect2, varscan2
- HIPK2 | c.215C>A p.P72Q | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs748732904, COSV100701940, COSV61225609; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs761272507; called by mutect2, varscan2
- HPSE | c.1393C>T p.R465W | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as rs565705065, COSV60986699; called by muse, mutect2, varscan2
- HTR1E | c.801del p.F268Sfs*5 | Frame Shift Del (DEL) | VAF 10/37 reads (27%) | catalogued as rs753568078, COSV59508996, COSV59509296; called by mutect2, pindel, varscan2
- IGFALS | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs756451070, COSV99236300; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs760925109; called by mutect2, pindel
- IQSEC3 | c.2026C>T p.R676C (on ENST00000538872 / NM_001170738.2; = p.R373C on NM_015232.1) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs139440816; called by muse, mutect2, varscan2
- JAK3 | c.184G>A p.G62S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.83); catalogued as rs199602590; called by muse, mutect2, varscan2
- KALRN | c.6812C>T p.A2271V (on ENST00000360013 / NM_001024660.4; = p.A574V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs753999093, COSV99360822; called by muse, mutect2, varscan2
- KCNJ12 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs782199360, COSV100053890; called by muse, mutect2, varscan2
- KIAA0895L | c.164del p.P55Qfs*32 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | catalogued as COSV99220418; called by mutect2, pindel, varscan2
- KIF11 | c.2932G>A p.V978I | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs1388783846, COSV99585582; called by muse, mutect2, varscan2
- KIF12 | c.1187G>A p.R396H (on ENST00000640217; = p.R258H on NM_138424.1) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs376905379; called by muse, mutect2, varscan2
- KLHL20 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV52944533; called by muse, mutect2, varscan2
- KMT2C | c.8532G>T p.E2844D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100065059; called by muse, mutect2, varscan2
- KRBA1 | c.2669G>A p.G890D | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as rs766369078, COSV99752096; called by muse, mutect2, varscan2
- LAMA5 | c.6383C>T p.T2128M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs368757053; called by muse, mutect2, varscan2
- LAMC1 | c.3401C>T p.A1134V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs148780198, COSV51154442; called by muse, mutect2, varscan2
- LRP2 | c.10472G>A p.C3491Y | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1558997025, COSV99786058; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRRC15 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100752446; called by muse, mutect2, varscan2
- LY9 | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV54433889, COSV99626053; called by muse, mutect2, varscan2
- LYPD6B | c.290C>T p.T97I (on ENST00000409029 / NM_001317004.1; = p.T121I on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.974); catalogued as COSV99700011; called by muse, mutect2, varscan2
- MACF1 | c.3169C>T p.R1057W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | catalogued as rs554979175, COSV100481857; called by muse, mutect2, varscan2
- MAFK | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); catalogued as rs561433493, COSV52474053; called by muse, mutect2, varscan2
- MAP1A | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.474); catalogued as rs1161643822, COSV100287935; called by muse, mutect2, varscan2
- MAP2K4 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.069); catalogued as rs753665559, COSV62255655; called by muse, mutect2, varscan2
- MCMDC2 | c.900G>C p.K300N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.299); catalogued as COSV100551595; called by muse, mutect2, varscan2
- MED12 | c.4478A>G p.D1493G | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV100375533; called by muse, mutect2, varscan2
- MIS18BP1 | c.2068del p.S690Vfs*10 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs750307488; called by mutect2, varscan2
- MMAA | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.284); catalogued as rs148142853; called by muse, mutect2, varscan2
- MSN | c.427A>G p.K143E | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1373451486, COSV100814052; called by muse, mutect2, varscan2
- MTCL1 | c.2572G>A p.E858K (on ENST00000306329 / NM_001378206.1; = p.E498K on NM_015210.4) | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.103); catalogued as rs774375780, COSV60405021; called by muse, mutect2, varscan2
- NCAPD2 | c.2508dup p.F837Lfs*11 | Frame Shift Ins (INS) | VAF 12/64 reads (19%) | catalogued as rs772347389; called by mutect2, varscan2
- NCEH1 | c.145T>C p.Y49H (on ENST00000538775; = p.Y17H on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99859714; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 11/31 reads (35%) | catalogued as rs759081520; called by mutect2, varscan2
- NLRC5 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52663288; called by muse, mutect2, varscan2
- NOTCH4 | c.2563C>T p.R855C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.232); catalogued as rs199620631, COSV100900295; called by muse, mutect2, varscan2
- OLFML1 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs532406645, COSV100252431; called by muse, mutect2, varscan2
- OLFML3 | c.875A>G p.D292G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1468912294, COSV100232910; called by muse, mutect2, varscan2
- OR4K15 | c.788C>T p.T263I (on ENST00000305051; = p.T239I on NM_001005486.1) | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1277770766, COSV100520952; called by muse, mutect2
- OR6C4 | c.303del p.F101Lfs*31 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as COSV67793317; called by mutect2, pindel, varscan2
- OR9K2 | c.978del p.K326Nfs*3 (on ENST00000305377; = p.K304Nfs*3 on NM_001005243.1) | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | catalogued as rs1249976011; called by mutect2, pindel, varscan2
- OTUB2 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99180137; called by muse, mutect2, varscan2
- PACS1 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs373127343; called by muse, mutect2, varscan2
- PALB2 | c.3494C>T p.S1165L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773829275, COSV55164051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PARD3 | c.1366del p.I456* | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs1484598500; called by mutect2, varscan2
- PASK | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs563062107, COSV52148560; called by muse, mutect2, varscan2
- PCDHA8 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 22/123 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV65336069; called by muse, varscan2
- PCNX2 | c.2677G>A p.A893T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs777681912, COSV50930960, COSV99265647; called by muse, mutect2, varscan2
- PCSK1 | c.1013G>A p.G338D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226760; called by muse, mutect2, varscan2
- PHF10 | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100199672; called by muse, mutect2, varscan2
- PHKA1 | c.2588G>T p.R863L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100262324; called by muse, mutect2, varscan2
- PLEKHG6 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1418710643, COSV99164027; called by muse, mutect2, varscan2
- PLS1 | c.418C>A p.P140T | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs775498545, COSV100537917; called by muse, mutect2, varscan2
- PLXNA1 | c.301G>A p.V101M | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.293); catalogued as rs1347349953, COSV99302111; called by muse, mutect2, varscan2
- PNLIPRP3 | c.1060C>G p.R354G | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as rs573172704, COSV100982288, COSV65047936; called by muse, varscan2
- PNPLA7 | c.2209G>A p.V737M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs375052362; called by muse, mutect2, varscan2
- PODN | c.1771G>A p.D591N (on ENST00000395871; = p.D543N on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.248); catalogued as rs534137326, COSV57010565; called by muse, mutect2, varscan2
- POPDC3 | c.439C>T p.Q147* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99633327; called by muse, mutect2, varscan2
- PPP1R10 | c.2084del p.G695Vfs*222 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | catalogued as rs760405117; called by pindel, varscan2
- PPP2R3C | c.67del p.S23Vfs*5 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | catalogued as rs758484975; called by mutect2, varscan2
- PRDM12 | c.320G>T p.W107L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.977); catalogued as COSV99446006; called by muse, mutect2, varscan2
- PRRX1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs780981143, CM143961, COSV53411170; called by muse, mutect2, varscan2
- PSMD9 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0.029); catalogued as COSV99945522; called by muse, mutect2
- PTCD1 | c.1562C>G p.T521R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV52866096; called by muse, mutect2, varscan2
- PTCH2 | c.2450G>T p.G817V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100941862; called by muse, mutect2, varscan2
- PTEN | c.800dup p.D268Gfs*30 | Frame Shift Ins (INS) | VAF 17/41 reads (41%) | catalogued as COSV64302388; called by mutect2, pindel, varscan2
- PYGB | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV99404779, COSV99405205; called by muse, mutect2, varscan2
- RAG2 | c.1496del p.K499Sfs*4 | Frame Shift Del (DEL) | VAF 30/136 reads (22%) | catalogued as rs1251406873; called by mutect2, pindel, varscan2
- RASGEF1C | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as rs1308935049, COSV100745438; called by muse, mutect2, varscan2
- RBFOX1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs757718956, COSV60946461, COSV60979056; called by muse, mutect2, varscan2
- RBM6 | c.2502del p.K834Nfs*27 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as COSV56484832; called by mutect2, varscan2
- RHBDF2 | c.932dup p.L312Tfs*52 | Frame Shift Ins (INS) | VAF 9/32 reads (28%) | catalogued as rs756639910; called by mutect2, varscan2
- ROBO4 | c.2738C>T p.A913V | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100127213; called by muse, mutect2, varscan2
- RSPO1 | c.638G>A p.R213K | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV100740455; called by mutect2, varscan2
- SCAF1 | c.3739G>A p.V1247I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV100566770; called by muse, mutect2, varscan2
- SEC16B | c.1520C>G p.S507W | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381148, COSV57624102; called by muse, mutect2, varscan2
- SEC24A | c.707A>G p.Q236R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as COSV100524274; called by muse, mutect2
- SEC31A | c.3319del p.I1107Lfs*13 (on ENST00000355196 / NM_001318120.1; = p.I1068Lfs*13 on NM_016211.4) | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs764353087, COSV52352147; called by mutect2, varscan2
- SFSWAP | c.2491G>A p.V831M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.003); catalogued as rs867767832, COSV99905697; called by muse, mutect2, varscan2
- SIRPA | c.1334C>T p.A445V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.434); catalogued as rs1246015069, COSV61538145; called by muse, mutect2, varscan2
- SKOR1 | c.40A>G p.I14V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV100408053; called by muse, mutect2, varscan2
- SLC1A1 | c.180G>A p.M60I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99261128; called by muse, mutect2, varscan2
- SLC39A12 | c.317T>A p.L106H | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV101069792, COSV66201204; called by muse, mutect2, varscan2
- SLC4A2 | c.2455G>A p.V819I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs752526026, COSV52540031; called by muse, mutect2, varscan2
- SLITRK1 | c.1303C>A p.L435M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as COSV100999741; called by muse, mutect2, varscan2
- SOX13 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs769776434, COSV65826683; called by muse, mutect2
- SQSTM1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759646319, CM128873, COSV52975093; called by muse, mutect2, varscan2
- SYNE1 | c.23137C>T p.R7713C (on ENST00000367255 / NM_182961.4; = p.R7642C on NM_033071.3) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs761198027, COSV54945602; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TCF7L2 | c.85_87del p.E29del | In Frame Del (DEL) | VAF 7/34 reads (21%) | catalogued as rs754968616; called by pindel, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs763321097; called by mutect2, varscan2
- TGS1 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99484971; called by muse, mutect2, varscan2
- THNSL2 | c.1037G>A p.R346K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV100147273, COSV100147400; called by muse, mutect2, varscan2
- TMEM41A | c.467del p.F156Sfs*5 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | catalogued as rs758476632; called by mutect2, varscan2
- TNMD | c.642del p.I216Lfs*12 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs754014575; called by mutect2, varscan2
- TNRC6C | c.1213A>C p.N405H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100049343; called by muse, mutect2
- TRIM13 | c.215A>T p.N72I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100078097; called by muse, mutect2
- TRIM50 | c.266G>A p.C89Y | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99333612; called by muse, mutect2
- TRMT1 | c.1247G>A p.S416N | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV55564509, COSV99678901; called by muse, mutect2, varscan2
- UBQLN4 | c.297del p.S100Pfs*72 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as rs1241270575; called by mutect2, pindel, varscan2
- UBR3 | c.4200G>T p.E1400D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99772952; called by muse, mutect2, varscan2
- UGT1A8 | c.156del p.H53Mfs*5 | Frame Shift Del (DEL) | VAF 28/114 reads (25%) | catalogued as COSV100990676; called by mutect2, varscan2
- UHRF1 | c.2110C>T p.R704W (on ENST00000612630 / NM_001290050.1; = p.R717W on NM_013282.4) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as rs760435882, COSV53577084; called by mutect2, varscan2
- UHRF1BP1L | c.3104T>C p.L1035S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs748900104, COSV99690968; called by muse, mutect2, varscan2
- UPF2 | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs748880785, COSV100706857; called by muse, mutect2, varscan2
- VIRMA | c.4919G>A p.R1640H | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52589461; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WIPF2 | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs748213735, COSV100063227; called by muse, mutect2, varscan2
- WWC2 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV100968101; called by muse, mutect2, varscan2
- XPO6 | c.2831G>A p.R944Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs762286015, COSV100484613; called by muse, mutect2, varscan2
- ZCCHC14 | c.2767C>T p.Q923* (on ENST00000268616; = p.Q1060* on NM_015144.3) | Nonsense Mutation (SNP) | VAF 31/101 reads (31%) | catalogued as COSV99233287; called by muse, mutect2, varscan2
- ZNF235 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.412); catalogued as COSV99349183; called by muse, mutect2, varscan2
- ZNF250 | c.1516C>T p.P506S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99480606; called by muse, mutect2, varscan2
- ZNF385C | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265856535, COSV100288733; called by muse, mutect2
- ZNF646 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs777007769, COSV100336267; called by muse, mutect2, varscan2
- ZNF778 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs199891318; called by muse, mutect2, varscan2
- ZNF98 | c.1654A>G p.N552D | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs759348425, COSV100757243; called by muse, mutect2, varscan2
- ZXDC | c.2326C>T p.R776W | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs540369236, COSV101071496; called by muse, mutect2, varscan2
- ACAP2 | c.1853del p.N618Tfs*15 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- AKAP5 | c.412del p.R138Gfs*8 | Frame Shift Del (DEL) | VAF 9/31 reads (29%) | called by mutect2, pindel, varscan2
- ARID1A | c.3216del p.K1072Nfs*21 | Frame Shift Del (DEL) | VAF 13/57 reads (23%) | called by mutect2, pindel, varscan2
- CAPN6 | c.29dup p.N10Kfs*20 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- CCT3 | c.1369del p.A457Pfs*24 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, varscan2
- CHPF2 | c.571dup p.R191Pfs*66 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, pindel, varscan2
- CPLANE2 | c.601del p.L201Cfs*4 | Frame Shift Del (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- DHRS7 | c.642del p.F214Lfs*14 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- DIP2A | c.2968del p.V990Cfs*18 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- EOMES | c.709dup p.A237Gfs*50 | Frame Shift Ins (INS) | VAF 5/32 reads (16%) | called by pindel, varscan2
- GLI2 | c.3859dup p.V1287Gfs*208 (on ENST00000361492 / NM_001374353.1; = p.V1304Gfs*208 on NM_005270.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel
- GOLGA4 | c.1276dup p.T426Nfs*14 | Frame Shift Ins (INS) | VAF 11/28 reads (39%) | called by mutect2, pindel, varscan2
- GPATCH2 | c.710dup p.T238Dfs*3 | Frame Shift Ins (INS) | VAF 17/98 reads (17%) | called by mutect2, pindel, varscan2
- HGS | c.1651_1653del p.K551del | In Frame Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- IGSF9B | c.646del p.E216Rfs*61 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- JARID2 | c.872del p.P291Lfs*16 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- KCNV2 | c.1419del p.F473Lfs*31 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- KIAA1522 | c.1535dup p.R513Tfs*41 (on ENST00000373480 / NM_001198972.2; = p.R572Tfs*41 on NM_020888.3) | Frame Shift Ins (INS) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- LRIT2 | c.1521del p.S508Afs*28 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | called by mutect2, pindel, varscan2
- LRRC49 | c.747_748del p.F250Sfs*4 | Frame Shift Del (DEL) | VAF 8/42 reads (19%) | called by pindel, varscan2
- MMP17 | c.1470del p.Y491Tfs*111 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- MXRA5 | c.4253del p.F1418Sfs*9 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- MYO3B | c.2459_2470del p.K820_W823del | In Frame Del (DEL) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- NPC1 | c.1554_1561del p.A519Lfs*4 | Frame Shift Del (DEL) | VAF 4/11 reads (36%) | called by mutect2, varscan2
- NPR2 | c.1314dup p.C439Lfs*4 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by pindel, varscan2
- OR6M1 | c.230dup p.L79Vfs*41 | Frame Shift Ins (INS) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- PARL | c.1122del p.G375Efs*12 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel, varscan2
- PLEC | c.1487del p.P496Lfs*40 (on ENST00000322810 / NM_201380.4; = p.P386Lfs*40 on NM_000445.5) | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- PSMB11 | c.23dup p.W9Vfs*5 | Frame Shift Ins (INS) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- PTPN5 | c.1409del p.P470Hfs*56 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel, varscan2
- RAB40AL | c.143del p.G48Efs*16 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- RASGEF1A | c.1160del p.K387Rfs*35 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- RASSF5 | c.963del p.F321Lfs*39 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- RELCH | c.719del p.N240Ifs*20 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- RPL22 | c.267del p.K89Nfs*3 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- SLC15A3 | c.1565del p.G522Afs*92 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- SLIT2 | c.3464del p.K1155Sfs*8 | Frame Shift Del (DEL) | VAF 13/56 reads (23%) | called by mutect2, pindel, varscan2
- TNFRSF8 | c.1478del p.G493Afs*28 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- TNRC6B | c.4523del p.G1508Vfs*8 (on ENST00000454349 / NM_001162501.2; = p.G1398Vfs*8 on NM_015088.3) | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- UBE3C | c.3065del p.P1022Lfs*31 | Frame Shift Del (DEL) | VAF 4/47 reads (9%) | called by mutect2, pindel
- XYLT2 | c.599del p.K200Rfs*9 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | called by mutect2, pindel, varscan2
- YTHDF2 | c.803del p.P268Rfs*2 | Frame Shift Del (DEL) | VAF 13/63 reads (21%) | called by mutect2, pindel, varscan2
- ZBTB7B | c.1007_1020del p.L336Pfs*91 (on ENST00000292176; = p.L370Pfs*91 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/24 reads (17%) | called by mutect2, pindel, varscan2
- ZNF57 | c.262del p.C88Vfs*13 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- ZNF613 | c.1194dup p.P399Tfs*6 (on ENST00000293471 / NM_001031721.4; = p.P363Tfs*6 on NM_024840.4) | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- ADAMTS14 | c.2175G>A p.K725= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1254871647; called by muse, mutect2
- ADAMTS7 | c.3165G>A p.P1055= | Silent (SNP) | VAF 15/183 reads (8%) | catalogued as rs372168680, COSV101183021; called by muse, mutect2
- ALS2CL | c.1284C>A p.T428= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100014648, COSV59673339; called by muse, mutect2, varscan2
- ANKRD50 | c.1990C>T p.L664= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV101538868; called by muse, mutect2, varscan2
- AWAT1 | c.477C>T p.S159= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100997163; called by muse, mutect2, varscan2
- BACH1 | c.1065C>T p.D355= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs776982426, COSV99727840; called by muse, varscan2
- BRSK2 | c.1551G>A p.A517= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs771846310, COSV100372216; called by muse, mutect2, varscan2
- CARMIL3 | c.3771A>G p.P1257= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99393021; called by muse, mutect2, varscan2
- CCDC136 | c.2079C>T p.D693= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs759968529, COSV99921980; called by muse, varscan2
- CETN2 | c.240G>A p.G80= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as rs782068050, COSV100938586; called by muse, mutect2, varscan2
- CHCHD5 | c.216C>T p.N72= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs573555238, COSV61424330; called by muse, mutect2, varscan2
- CNTLN | c.2880T>C p.V960= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV99262421; called by muse, mutect2, varscan2
- COL18A1 | c.2061C>T p.P687= (on ENST00000359759 / NM_130444.3; = p.P452= on NM_030582.4) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100700380; called by muse, mutect2, varscan2
- CPN1 | c.651A>G p.G217= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as rs1372751284; called by muse, mutect2
- CPPED1 | c.915C>T p.D305= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs1308071330, COSV99902659; called by muse, mutect2
- CTCF | c.1527C>T p.H509= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1450708641, COSV99864131; called by muse, mutect2, varscan2
- CYP4F8 | c.813C>T p.I271= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100357973; called by muse, mutect2, varscan2
- DAP3 | c.1008C>T p.A336= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100546331; called by muse, mutect2, varscan2
- DAPK1 | c.4086G>A p.L1362= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs768819316, COSV100800776; called by muse, mutect2, varscan2
- DCLK1 | c.2010C>T p.N670= | Silent (SNP) | VAF 28/91 reads (31%) | catalogued as COSV99708664; called by muse, mutect2, varscan2
- DDX60 | c.2250T>C p.D750= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as COSV101190203; called by muse, mutect2, varscan2
- DOCK2 | c.4326C>T p.F1442= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99909712; called by muse, mutect2, varscan2
- ELK1 | c.243C>T p.F81= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs763088656, COSV55953832; called by muse, mutect2
- EXPH5 | c.3702G>A p.T1234= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs746335515, COSV99760794; called by muse, mutect2, varscan2
- FAM47C | c.2004G>A p.P668= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as rs782772942, COSV63727168; called by muse, mutect2, varscan2
- GC | c.1276C>T p.L426= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99909329; called by muse, mutect2, varscan2
- GGT6 | c.196C>T p.L66= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV99625225; called by muse, mutect2, varscan2
- GPX4 | c.357C>T p.F119= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs757440433, COSV100683934; called by muse, mutect2, varscan2
- HOXB1 | c.597C>T p.G199= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99495262; called by muse, mutect2, varscan2
- IKBIP | c.759C>T p.F253= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as rs760314864, COSV61082645; called by muse, mutect2, varscan2
- ITIH4 | c.1725G>A p.A575= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1318814009, COSV99818784; called by mutect2, varscan2
- JRKL | c.702T>C p.P234= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99567012; called by muse, mutect2, varscan2
- KCNQ2 | c.822G>A p.T274= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as rs377485599, COSV60434539; called by muse, mutect2, varscan2
- LAMB3 | c.1806C>T p.L602= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV61916011; called by muse, mutect2, varscan2
- LRP10 | c.1623C>T p.G541= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100612241; called by muse, mutect2, varscan2
- MMP15 | c.1962G>A p.A654= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as rs147317164; called by muse, mutect2
- MUC5B | c.2751C>T p.C917= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs745400423, COSV101499969; called by muse, mutect2, varscan2
- MYO9B | c.5076C>T p.G1692= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1269830602, COSV68283033; called by muse, mutect2, varscan2
- NAV2 | c.1386C>T p.S462= (on ENST00000396087 / NM_001244963.2; = p.S439= on NM_145117.5) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs769720452, COSV62328027; called by muse, mutect2
- NOTCH1 | c.1269C>T p.C423= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs775219296, COSV53036462, COSV99484406; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4C16 | c.240T>A p.I80= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100113773; called by muse, mutect2
- OR56A3 | c.75C>T p.P25= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100289997, COSV100290265; called by muse, mutect2, varscan2
- P2RY6 | c.882C>T p.S294= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs542361416, COSV62936301; called by muse, mutect2, varscan2
- PCDHB6 | c.2229A>G p.L743= | Silent (SNP) | VAF 5/78 reads (6%) | catalogued as rs782241605, COSV99169883; called by muse, mutect2
- PFKM | c.177C>A p.T59= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99136757; called by muse, mutect2, varscan2
- PGBD1 | c.460T>C p.L154= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99459571; called by muse, mutect2, varscan2
- PLCG2 | c.921C>T p.D307= | Silent (SNP) | VAF 27/78 reads (35%) | catalogued as rs533700490, COSV63872801; called by muse, mutect2, varscan2
- PLCG2 | c.1866G>A p.L622= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV100842023; called by muse, mutect2, varscan2
- PLXND1 | c.5691G>A p.T1897= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs761700156, COSV100138871; called by muse, mutect2, varscan2
- POLG | c.1305G>A p.L435= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99174449; called by muse, mutect2, varscan2
- PRDM10 | c.1455G>A p.P485= | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs1437681431, COSV100456524; called by muse, mutect2, varscan2
- PRKAG3 | c.1191C>A p.S397= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV99291709; called by muse, mutect2, varscan2
- PSD3 | c.2466A>C p.T822= (on ENST00000440756; = p.T821= on NM_015310.4) | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99675091; called by muse, mutect2, varscan2
- PTOV1 | c.411G>A p.P137= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as rs371342339; called by muse, mutect2, varscan2
- RAPH1 | c.2928G>A p.Q976= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs746761130, COSV99863273; called by mutect2, varscan2
- RIC3 | c.567T>C p.H189= (on ENST00000309737 / NM_001206671.4; = p.H188= on NM_024557.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV100111518; called by muse, mutect2, varscan2
- RPS16 | c.432C>A p.S144= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs912918370, COSV99261738; called by muse, mutect2, varscan2
- SEZ6L2 | c.2274C>T p.S758= (on ENST00000308713 / NM_001114099.3; = p.S688= on NM_012410.4) | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs150405329; called by muse, mutect2, varscan2
- SLC7A6 | c.591C>T p.Y197= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs754259458, COSV99546332; called by muse, mutect2
- SORCS3 | c.1680C>A p.S560= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs758054022, COSV63807483, COSV63814917; called by muse, mutect2, varscan2
- SPNS2 | c.759G>A p.K253= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV100223385; called by muse, mutect2, varscan2
- STIP1 | c.819C>T p.G273= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs774373870, COSV59438223; called by muse, mutect2, varscan2
- TNS3 | c.2364G>A p.L788= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100234525; called by muse, mutect2, varscan2
- TP63 | c.546G>A p.Q182= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV53221476; called by muse, mutect2
- TSPAN11 | c.429C>T p.T143= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs373232812; called by muse, mutect2, varscan2
- USP19 | c.1041G>A p.Q347= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs930797106, COSV100025722; called by muse, mutect2, varscan2
- VRK1 | c.936T>C p.T312= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99388144; called by muse, mutect2, varscan2
- ZFHX3 | c.2814C>T p.N938= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs199635500, COSV51709091; called by muse, mutect2, varscan2
- ZNF532 | c.2076T>C p.V692= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100265816, COSV100265874; called by muse, mutect2, varscan2
- ZSCAN10 | c.954G>A p.G318= (on ENST00000252463; = p.G373= on NM_032805.3) | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99373766; called by muse, mutect2
- CAPN1 | chr11:65214010 del C | 3'Flank (DEL) | VAF 18/66 reads (27%) | catalogued as rs746296618; called by mutect2, varscan2
- CXXC5 | c.*1C>T | 3'UTR (SNP) | VAF 8/37 reads (22%) | catalogued as rs780702891, COSV100210510; called by muse, mutect2, varscan2
- MROH8 | chr20:37160153 C>T | 5'Flank (SNP) | VAF 10/19 reads (53%) | catalogued as rs369779752; called by muse, mutect2, varscan2
- PTBP1 | c.892+329C>T | Intron (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100608269; called by muse, mutect2, varscan2
- VAV3 | c.-2G>A | 5'UTR (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100894178; called by muse, mutect2, varscan2
